Somatic mutation profile of tumor specimen TARGET-10-PATDKT-09A (aliquot TARGET-10-PATDKT-09A-01D) from TARGET case TARGET-10-PATDKT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.4 years (8,169 days).
Specimen TARGET-10-PATDKT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 310d3eec-e745-4913-a872-a7fc6440decc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATDKT-10A (Blood Derived Normal), aliquot TARGET-10-PATDKT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ab6eaf-39d9-4b27-b83d-8435f90d6057

The open-access MAF lists 36 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 5, Silent 5, RNA 3, In Frame Ins 2, Nonsense Mutation 2, In Frame Del 1, 5'UTR 1, 3'UTR 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCS1L | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55310465; called by muse, mutect2, varscan2
- CDH20 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs762896499, COSV53010082, COSV53016279; called by muse, mutect2, varscan2
- CREB1 | c.970A>G p.T324A (on ENST00000432329 / NM_134442.5; = p.T310A on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV62065595; called by muse, mutect2, varscan2
- DNAH3 | c.5194G>A p.A1732T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs562202929, COSV54535935; called by muse, mutect2, varscan2
- FAM133A | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 15/15 reads (100%) | catalogued as rs1253520045, COSV59078482; called by muse, mutect2, varscan2
- GOLGA3 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV52629481, COSV52648507; called by muse, mutect2, varscan2
- IL7R | c.725_726insTTGCACTCCAGTCCC p.L242delinsFCTPVP | In Frame Ins (INS) | VAF 22/65 reads (34%) | catalogued as COSV57415806; called by mutect2, pindel, varscan2
- KRT14 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs576427037, COSV51423644; called by muse, mutect2, varscan2
- NOTCH1 | c.7246C>T p.Q2416* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1564567815, COSV53067965; called by muse, mutect2, varscan2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2
- OAZ3 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV58618710, COSV58619972, COSV58620751; called by muse, mutect2, varscan2
- PADI6 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.285); catalogued as rs766402946, COSV61886068; called by muse, mutect2, varscan2
- RING1 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63003104; called by muse, mutect2, varscan2
- RP1L1 | c.7144G>A p.A2382T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776156711, COSV66762092; called by muse, mutect2, varscan2
- SERPINA11 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV58243921; called by muse, mutect2, varscan2
- ST8SIA3 | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 23/42 reads (55%) | PolyPhen possibly damaging (0.542); catalogued as rs756634608, COSV60654674; called by muse, mutect2, varscan2
- CSDE1 | c.194_196del p.V65del | In Frame Del (DEL) | VAF 11/25 reads (44%) | called by mutect2, pindel
- OGT | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC6 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- XPO1 | c.3089_3093delinsTTCCCTTCGTTCGG p.T1030_S1031delinsIPFVR | In Frame Ins (INS) | VAF 44/85 reads (52%) | called by pindel, varscan2*
- ATP7A | c.1593G>A p.R531= | Silent (SNP) | VAF 79/82 reads (96%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1332C>A p.S444= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV57602442; called by muse, mutect2, varscan2
- OR4K1 | c.909C>T p.N303= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as rs764530895, COSV53463002; called by muse, mutect2, varscan2
- TRIOBP | c.6456G>A p.T2152= (on ENST00000644935 / NM_001039141.3; = p.T439= on NM_007032.5) | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs372723886; called by muse, varscan2
- ZFAT | c.705A>G p.S235= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- C1S | c.392-76T>C | Intron (SNP) | VAF 42/80 reads (53%) | catalogued as rs1423291926; called by muse, mutect2, varscan2
- C8orf87 | n.24C>A | RNA (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CAPN3 | c.1537-40C>T | Intron (SNP) | VAF 5/12 reads (42%) | catalogued as CS062043; called by muse, mutect2, varscan2
- ETFDH | c.176-15T>G | Intron (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- F2RL2 | c.-107C>A | 5'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.655C>T | RNA (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- LINC01949 | n.946C>G | RNA (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- P2RX1 | c.137+225A>C | Intron (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- RFX7 | c.*5869C>A | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- SNED1 | c.2372-49C>T | Intron (SNP) | VAF 26/60 reads (43%) | catalogued as rs777982460; called by muse, mutect2, varscan2
- Unknown | chr17:43377587 C>T | IGR (SNP) | VAF 16/39 reads (41%) | catalogued as rs778401421; called by muse, mutect2, varscan2
